Gene-level copy-number profile of tumor specimen TCGA-AC-A6IX-06A from TCGA case TCGA-AC-A6IX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.2 years (17,969 days).
Specimen TCGA-AC-A6IX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.98022470-8d33-46c2-b162-78626a3eb4b7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A6IX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/387a027e-dc12-4e17-a914-6373b8af3da2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 555; copy number 1: 7,507; copy number 2: 47,873; copy number 3: 3,190; copy number 4: 15; copy number 5: 92; copy number 6: 110; copy number 7: 479; copy number 8: 298; copy number 9: 103; copy number 11: 8; copy number 12: 2; copy number 14: 13; copy number 19: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A6IX-06A-11D-A32H-01): tumor purity 0.29, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:93,828,753–93,830,964, 1 gene (within-gene range 0–2): ATOH1.
- chr8:64,456,198–65,842,322, 20 genes: AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:112,602,354–112,602,452, 1 gene: AP003063.1.
- chr17:18,450,244–18,551,705, 9 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–2): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene: AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,121 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–148,519,604, 159 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr1:148,358,245–151,771,334, 162 genes, copy number 8 (broad region; genes not listed).
- chr8:91,909,738–92,421,798, 8 genes, copy number 6: PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3.
- chr8:97,853,021–99,013,743, 30 genes, copy number 6: AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1.
- chr8:99,091,738–99,348,256, 5 genes, copy number 6: AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1.
- chr8:100,150,623–101,492,499, 48 genes, copy number 6–11 (within-gene range 3–11): POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr8:104,590,733–105,804,539, 1 gene, copy number 14 (within-gene range 3–14): ZFPM2.
- chr8:104,981,164–107,498,055, 25 genes, copy number 8–19 (within-gene range 2–19): AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1.
- chr8:109,086,585–124,539,458, 169 genes, copy number 6–19 (within-gene range 2–19) (broad region; genes not listed).
- chr11:57,233,577–61,969,490, 220 genes, copy number 5–7 (broad region; genes not listed).
- chr11:68,312,591–71,252,577, 68 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:75,815,210–76,144,232, 1 gene, copy number 7 (within-gene range 2–7): UVRAG.
- chr11:75,911,204–78,582,156, 72 genes, copy number 7 (broad region; genes not listed).
- chr11:86,791,059–87,025,777, 10 genes, copy number 7: PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8.
- chr11:87,094,734–87,121,596, 2 genes, copy number 7: XIAPP2, AP002967.1.
- chr11:87,480,736–87,721,233, 7 genes, copy number 5: AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1.
- chr14:105,764,503–106,369,546, 104 genes, copy number 8 (broad region; genes not listed).
- chr16:35,207,884–35,284,146, 1 gene, copy number 5 (within-gene range 2–5): AC023824.3.
- chr16:35,232,412–35,529,318, 28 genes, copy number 5–6: FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5.
- chr21:45,914,296–45,919,483, 1 gene, copy number 5: AJ239328.1.

Autosomal genes at a single copy (total copy number 1): 7,474. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
